Gene-level copy-number profile of specimen HCM-BROD-0254-C49-85N from HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 42aeb296-fcbe-48ff-ac6a-622319b71808.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0254-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/1039e446-f062-4693-a3da-1c0094737a14

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4; copy number 2: 3,243; copy number 3: 25,503; copy number 4: 14,016; copy number 5: 11,166; copy number 6: 4,429; copy number 7: 497; copy number 8: 33; copy number 9: 8; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,439,069–32,441,159, 1 gene: PABPC1P13.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 540 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,108,210–121,398,806, 8 genes, copy number 7–8 (within-gene range 6–8): H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1.
- chr2:23,357,516–25,159,135, 45 genes, copy number 7: AC012506.2, AC012506.4, KLHL29, AC011239.1, AC011239.2, AC009242.1, ATAD2B, PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A, AC008073.1, ITSN2, AC009228.1, AC009228.2, HMGN2P20, RPL36AP13, NCOA1, RNA5SP88, RNU6-936P, PTRHD1, CENPO, ADCY3, AC012073.1, DNAJC27, RPS13P5, SNORD14, DNAJC27-AS1, AC013267.1, Y_RNA, EFR3B, RN7SL856P, SUCLA2P3.
- chr2:89,319,625–89,600,680, 3 genes, copy number 7: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:89,906,757–90,100,738, 18 genes, copy number 7–9: IGKV3D-34, IGKV1D-33, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16.
- chr2:90,179,889–90,367,699, 9 genes, copy number 9–10: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr7:85,381,118–85,381,375, 1 gene, copy number 7: DYNLL1P7.
- chr9:32,820,261–32,869,595, 3 genes, copy number 7: Y_RNA, AL157884.3, AL157884.2.
- chr9:32,926,051–32,926,450, 1 gene, copy number 7: BOLA3P4.
- chr9:33,218,365–33,248,567, 1 gene, copy number 7 (within-gene range 6–7): SPINK4.
- chr13:18,467,172–40,611,127, 419 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr21:9,325,013–13,120,807, 32 genes, copy number 7–8: CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
